Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6399, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6399-01A (Primary Tumor).

AGE/SEX: [REDACTED] DOB: [REDACTED] SURGERY DATE: [REDACTED]
RECEIVE DATE: [REDACTED]

PATHOLOGICAL DIAGNOSIS:

A-C. BRAIN, TEMPORAL LOBE, BIOPSY: OLIGODENDROGLIOMA (MIB-1: 8-10%).

Operation/Specimen: FS brain tumor. 2) Temporal lobe lesion.
3) Temporal lobe tissue.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: Three parts.

A.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: Single, 0.4 cm. maximum dimension soft, tan-brown fragment, smears prepared and portion submitted for frozen section examination.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glial proliferation r/o low grade glioma. [REDACTED]

SECTIONS: 1 - frozen section control.

B.

SPECIMEN: Temporal lobe lesion.

FIXATIVE: None.

GENERAL: Single 1.3 x 0.5 cm. gray-tan piece.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Smears and frozen section prepared. Brain: Glial proliferation r/o low grade glioma [REDACTED]

C.

SPECIMEN: Temporal lobe lesion, permanent.

FIXATIVE: None.

GENERAL: Multiple tan-brown fragments 8 x 5 x 3 cm. in aggregate.

SECTIONS: 4-9 - representative.

MICROSCOPIC: A-C. Nine blocks, nine slides. Sections show a diffusely infiltrating glial tumor composed of cells with round nuclei and a "fried egg" appearance. There is focal hypercellularity and microcystic change. Several microgemistocytes are present within the lesion. No mitotic activity or vascular endothelial proliferation is noted. The features are of an oligodendroglioma, grade B. MIB-1 is about 8-10%.

Source: NCI Genomic Data Commons file e8919c8c-ed00-4afe-8782-97962500d659 (TCGA-DU-6399.E0803E30-AE37-4C26-8D3B-BC0A3EE88A51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).